Somatic mutation profile of tumor specimen TCGA-KC-A7FA-01A (aliquot TCGA-KC-A7FA-01A-21D-A33T-08) from TCGA case TCGA-KC-A7FA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,208 days).
Specimen TCGA-KC-A7FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d015c0d-4a5a-4202-9efe-b4f10629f905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A7FA-10A (Blood Derived Normal), aliquot TCGA-KC-A7FA-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28873773-d510-4a4e-8758-115dd5ad0f04

The open-access MAF lists 37 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 3, Frame Shift Ins 2, Intron 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PNPLA1 | c.514G>A p.D172N (on ENST00000394571 / NM_001374623.1; = p.D77N on NM_173676.2) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373148099; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.993+2T>G p.X331_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | hotspot (GDC flag); catalogued as COSV52703680, COSV52798259, COSV52814192; called by muse, varscan2
- ADAMTS9 | c.5444G>T p.C1815F | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99898747; called by muse, mutect2, varscan2
- APBA1 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99595440; called by muse, mutect2, varscan2
- AUTS2 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as COSV100715016; called by muse, mutect2, varscan2
- CHAF1A | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as rs139033845; called by muse, mutect2, varscan2
- CPS1 | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772782772, CM114355, COSV99242192; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- CR1 | c.4053C>A p.D1351E | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs938044503, COSV100887392; called by muse, mutect2, varscan2
- DPYSL4 | c.1445T>G p.I482S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100061815; called by muse, mutect2, varscan2
- ECD | c.541A>C p.I181L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs775919239, COSV100881348; called by muse, mutect2, varscan2
- ENTPD4 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652508; called by muse, mutect2, varscan2
- FAM135B | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52749802, COSV99418979, COSV99424084; called by muse, mutect2, varscan2
- FILIP1 | c.3274G>T p.V1092F | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.691); catalogued as COSV99383881; called by muse, mutect2, varscan2
- ITGB6 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99324145; called by muse, mutect2, varscan2
- JMJD1C | c.2948G>C p.R983T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100550133; called by muse, mutect2, varscan2
- LRP12 | c.800A>C p.Y267S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV99407208; called by muse, mutect2, varscan2
- MAP3K13 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99406444, COSV99407236; called by muse, mutect2, varscan2
- NPY5R | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs767017396, COSV100642640; called by muse, mutect2, varscan2
- OR6K2 | c.940dup p.S314Ffs*9 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs764050222; called by mutect2, varscan2
- PTPDC1 | c.1376C>G p.S459* (on ENST00000375360 / NM_177995.3; = p.S511* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99997335; called by muse, mutect2, varscan2
- RSPH3 | c.342dup p.H115Tfs*35 | Frame Shift Ins (INS) | VAF 28/91 reads (31%) | catalogued as rs765099471; called by mutect2, pindel, varscan2
- RYR2 | c.5921A>G p.N1974S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV100767931; called by muse, mutect2, varscan2
- SCN2B | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs936800643, COSV99635507; called by muse, mutect2, varscan2
- SELENOI | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs775919741, COSV99564188; called by muse, mutect2, varscan2
- SFRP2 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99923167; called by muse, mutect2, varscan2
- SIN3B | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs781358567, COSV56131596; called by muse, mutect2, varscan2
- SMC2 | c.2048A>G p.D683G | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99658359; called by muse, mutect2
- SPAG6 | c.339T>G p.H113Q | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100509947; called by muse, mutect2, varscan2
- KMT2D | c.10034_10049del p.P3345Rfs*8 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- TRAV26-1 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- BEND7 | c.1038G>A p.A346= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs770522587, COSV100346371; called by muse, mutect2, varscan2
- LRIG1 | c.315A>G p.T105= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV99833250; called by muse, mutect2, varscan2
- PCDHB1 | c.123C>T p.S41= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV60633925; called by muse, mutect2, varscan2
- SRGAP2 | c.1620C>G p.A540= (on ENST00000624873 / NM_001170637.4; = p.A541= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99832404; called by muse, mutect2
- TIMD4 | c.210C>T p.R70= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99192492; called by muse, mutect2, varscan2
- LY9 | c.454+1823G>A | Intron (SNP) | VAF 12/98 reads (12%) | catalogued as COSV99626198; called by muse, mutect2
- PLPP1 | c.59-15580A>G | Intron (SNP) | VAF 3/43 reads (7%) | catalogued as rs1455736955, COSV99301385; called by muse, mutect2
